Somatic mutation profile of tumor specimen MP2PRT-PAVUXV-TMP1-A (aliquot MP2PRT-PAVUXV-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVUXV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,173 days).
Specimen MP2PRT-PAVUXV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 589eb156-0a5d-4cd0-8fcb-a7a720b0cb46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUXV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUXV-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68788979-bb0d-49bb-97ad-1764ea70badf

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Frame Shift Ins 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP12 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 79/405 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs149211517; called by muse, mutect2, varscan2
- CTNNBIP1 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 88/362 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs548974391, COSV101032689; called by muse, mutect2, varscan2
- FAM135B | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs538879681, COSV104372656; called by muse, varscan2
- GOLGA6L1 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 100/1086 reads (9%) | catalogued as rs774619627; called by muse, mutect2
- HCN1 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 154/549 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as COSV57496411, COSV57526158; called by muse, mutect2, varscan2
- HMCN1 | c.7493C>T p.T2498M | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as rs760153934, COSV54897877; called by muse, mutect2, varscan2
- MATN4 | c.1153G>A p.V385M (on ENST00000372754; = p.V344M on NM_003833.4) | Missense Mutation (SNP) | VAF 99/325 reads (30%) | PolyPhen benign (0.19); catalogued as rs536499118; called by muse, mutect2, varscan2
- PDS5B | c.2170dup p.R724Pfs*16 | Frame Shift Ins (INS) | VAF 38/172 reads (22%) | catalogued as rs746601412; called by mutect2, varscan2
- UBA2 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99875485; called by muse, mutect2, varscan2
- COL11A1 | c.4043G>T p.G1348V | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL11A1 | c.4042G>A p.G1348S | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXB3 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 232/739 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV4-61 | c.353_354insTTGGAGACGGGAG p.R118Sfs*? | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by pindel, varscan2
- KDM5D | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 195/349 reads (56%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBTD1 | c.174G>A p.A58= | Silent (SNP) | VAF 137/488 reads (28%) | catalogued as rs144202501; called by muse, varscan2
